Gene-level copy-number profile of tumor specimen HCM-CSHL-0622-C18-06A from HCMI case HCM-CSHL-0622-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: GX; Age at diagnosis: 78.3 years (28,592 days).
Specimen HCM-CSHL-0622-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7b2274b3-4822-4427-b95e-1d4b17d6fc53.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0622-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/bb267bc6-60ba-4e07-bbf2-5f0f5f617815

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 804; copy number 2: 46,466; copy number 3: 9,092; copy number 4: 1,261; copy number 5: 730; copy number 7: 35.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:34,489,002–34,521,791, 3 genes: HNRNPLP2, FSCN1P1, DNM1P5.
- chr16:7,004,007–7,004,112, 1 gene (within-gene range 0–2): RNU6-328P.
- chr18:50,795,120–51,085,045, 8 genes: MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 765 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,243,212–118,264,489, 16 genes, copy number 5: Metazoa_SRP, LINC01525, AL358072.1, MAN1A2, AL157902.2, VPS25P1, AL157902.1, TENT5C, VDAC2P3, AL390877.1, AL390877.2, PNRC2P1, GDAP2, WDR3, SPAG17, RNA5SP56.
- chr1:182,598,623–183,472,265, 22 genes, copy number 7 (within-gene range 3–7): RGS16, LINC01686, RGS8, LINC01688, AL353778.1, NPL, AL355999.1, DHX9, SHCBP1L, HMGN1P4, 5S_rRNA, AL450304.1, KRT18P28, RNU6-41P, LAMC1, LAMC1-AS1, LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1.
- chr5:58,198–25,350,073, 396 genes, copy number 5 (broad region; genes not listed).
- chr5:25,701,217–45,895,970, 281 genes, copy number 5 (broad region; genes not listed).
- chr20:52,972,358–53,495,330, 1 gene, copy number 7 (within-gene range 3–7): TSHZ2.
- chr20:53,137,293–56,786,087, 49 genes, copy number 5–7: AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P.

Autosomal genes at a single copy (total copy number 1): 802. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
